CCDI case PBCWNL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3d65b2b7-feac-44a4-b93e-585c27736237

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1NYS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1O0G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E1O0T: Tissue type: Tumor; Specimen type: Solid Tissue.
